Somatic mutation profile of tumor specimen TCGA-BG-A0MU-01A (aliquot TCGA-BG-A0MU-01A-11D-A10B-09) from TCGA case TCGA-BG-A0MU, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIA; Tumor grade: G1; Age at diagnosis: 78.4 years (28,621 days).
Specimen TCGA-BG-A0MU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a4717ff4-8ce7-4121-8c0b-23eb04ef030f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BG-A0MU-10A (Blood Derived Normal), aliquot TCGA-BG-A0MU-10A-02D-A10B-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d5f28aa2-aee8-4651-aed6-e77b855da17c

The open-access MAF lists 72 somatic variants for this specimen: 52 protein-altering or splice-affecting, 19 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 46, Silent 19, In Frame Del 2, Frame Shift Del 2, Frame Shift Ins 1, Intron 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BCOR | c.4376A>G p.N1459S (on ENST00000378444 / NM_001123385.2; = p.N1425S on NM_017745.6) | Missense Mutation (SNP) | VAF 106/232 reads (46%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.578); catalogued as rs199538037, COSV60698733; called by muse, mutect2, varscan2
- CTNNB1 | c.100G>A p.G34R | Missense Mutation (SNP) | VAF 24/58 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913399, COSV62687911, COSV62687931, COSV62721471; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ESR1 | c.1613A>G p.D538G | Missense Mutation (SNP) | VAF 70/170 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV52781024; called by muse, mutect2, varscan2
- PIK3R1 | c.1737_1739del p.Q579_Y580delinsH (on ENST00000521381 / NM_181523.3; = p.Q309_Y310delinsH on NM_181504.4) | In Frame Del (DEL) | VAF 121/276 reads (44%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- PTEN | c.388C>G p.R130G | Missense Mutation (SNP) | VAF 126/144 reads (88%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121909224, CM094223, CM971273, COSV64288384, COSV64288463, COSV64297940, COSV64311187; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADAMTS3 | c.1721G>A p.R574K | Missense Mutation (SNP) | VAF 28/54 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54404742; called by muse, mutect2, varscan2
- BMP1 | c.355C>T p.R119W | Missense Mutation (SNP) | VAF 77/168 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as rs1262108882, COSV59244758; called by muse, mutect2, varscan2
- CLDN11 | c.565C>T p.R189C | Missense Mutation (SNP) | VAF 96/209 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.801); catalogued as rs748307543, COSV50356310; called by muse, mutect2, varscan2
- CNBD2 | c.607G>A p.V203I | Missense Mutation (SNP) | VAF 94/222 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as rs750702259, COSV62586269; called by muse, mutect2, varscan2
- CYFIP2 | c.848A>G p.K283R | Missense Mutation (SNP) | VAF 90/197 reads (46%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.678); catalogued as COSV59053473, COSV99041124; called by muse, mutect2, varscan2
- DEF6 | c.491A>C p.E164A | Missense Mutation (SNP) | VAF 39/105 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.15); catalogued as COSV57355674; called by muse, mutect2, varscan2
- DNAH5 | c.5754A>C p.K1918N | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV54257000; called by muse, mutect2, varscan2
- EP300 | c.3377A>G p.N1126S | Missense Mutation (SNP) | VAF 52/140 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs777847755, COSV54347133; called by muse, mutect2, varscan2
- FNDC3B | c.605G>T p.R202L | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.416); catalogued as COSV61050359, COSV61051009; called by muse, mutect2, varscan2
- GJA8 | c.364G>A p.G122S | Missense Mutation (SNP) | VAF 63/181 reads (35%) | SIFT tolerated (0.68); PolyPhen benign (0.007); catalogued as rs1553242652, COSV53790279; called by muse, mutect2, varscan2
- GJB5 | c.292C>T p.R98W | Missense Mutation (SNP) | VAF 53/123 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199724435; called by muse, mutect2, varscan2
- GPR32 | c.585C>G p.F195L | Missense Mutation (SNP) | VAF 74/168 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.241); catalogued as rs1354818745, COSV54515844; called by muse, mutect2, varscan2
- GRIA1 | c.2666C>T p.S889L | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.018); catalogued as COSV53627933; called by muse, mutect2, varscan2
- H2BC13 | c.13G>A p.A5T | Missense Mutation (SNP) | VAF 121/290 reads (42%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.056); catalogued as rs142297357, COSV62441005; called by muse, mutect2, varscan2
- JHY | c.304del p.E102Sfs*18 | Frame Shift Del (DEL) | VAF 59/143 reads (41%) | catalogued as COSV56222191; called by mutect2, pindel, varscan2
- KCNC4 | c.83A>T p.E28V | Missense Mutation (SNP) | VAF 51/107 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.198); catalogued as COSV63926860; called by muse, mutect2, varscan2
- KLRC4 | c.316T>C p.S106P | Missense Mutation (SNP) | VAF 65/114 reads (57%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.804); catalogued as COSV58672670; called by muse, mutect2, varscan2
- KRTAP5-1 | c.811C>T p.P271S | Missense Mutation (SNP) | VAF 29/369 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.917); catalogued as COSV66299369; called by muse, mutect2
- NOVA2 | c.263C>T p.T88M | Missense Mutation (SNP) | VAF 201/470 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs781569043, COSV54357194, COSV54360362; called by muse, mutect2, varscan2
- NPAP1 | c.884C>T p.P295L | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs552546592, COSV61504273; called by muse, mutect2, varscan2
- NRK | c.3241G>T p.E1081* | Nonsense Mutation (SNP) | VAF 38/76 reads (50%) | catalogued as COSV54608733; called by muse, mutect2, varscan2
- OBSCN | c.9925T>C p.S3309P | Missense Mutation (SNP) | VAF 26/592 reads (4%) | SIFT tolerated (0.35); PolyPhen benign (0.021); catalogued as COSV52840177; called by muse, mutect2
- OFD1 | c.1234T>C p.S412P | Missense Mutation (SNP) | VAF 41/79 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV60799469; called by muse, mutect2, varscan2
- OR4A15 | c.614G>T p.C205F | Missense Mutation (SNP) | VAF 78/176 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.971); catalogued as COSV59034088; called by muse, mutect2, varscan2
- OR5D14 | c.514G>A p.G172R | Missense Mutation (SNP) | VAF 97/241 reads (40%) | SIFT tolerated (0.25); PolyPhen benign (0.25); catalogued as rs1386012170, COSV59459093; called by muse, mutect2, varscan2
- PCM1 | c.5369C>G p.T1790S | Missense Mutation (SNP) | VAF 14/160 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.09); catalogued as COSV59589187; called by muse, mutect2
- PGBD5 | c.413G>A p.R138H (on ENST00000525115; = p.R207H on NM_001258311.2) | Missense Mutation (SNP) | VAF 44/131 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1311026622, COSV58413936; called by muse, mutect2, varscan2
- PJA1 | c.1658C>T p.A553V (on ENST00000361478 / NM_145119.4; = p.A365V on NM_022368.5) | Missense Mutation (SNP) | VAF 67/181 reads (37%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.98); catalogued as rs199707327, COSV64052764, COSV64053674; called by muse, mutect2, varscan2
- POM121L12 | c.809C>T p.A270V | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as rs775755313, COSV68694032; called by muse, mutect2, varscan2
- RFC2 | c.317A>G p.N106S | Missense Mutation (SNP) | VAF 44/108 reads (41%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.451); catalogued as rs781895699, COSV50017218; called by muse, mutect2, varscan2
- SARDH | c.1090G>A p.A364T | Missense Mutation (SNP) | VAF 71/190 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.909); catalogued as rs775453942, COSV64096284; called by muse, mutect2, varscan2
- SEMA6C | c.128C>T p.P43L | Missense Mutation (SNP) | VAF 33/101 reads (33%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.991); catalogued as COSV59008529; called by muse, mutect2, varscan2
- SLC4A8 | c.1561G>A p.G521R | Missense Mutation (SNP) | VAF 89/201 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60654541; called by muse, varscan2
- SLC5A2 | c.1031C>T p.A344V | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs766548165, CM161454, COSV57895050; called by muse, mutect2, varscan2
- SORCS3 | c.2806G>T p.V936F | Missense Mutation (SNP) | VAF 56/124 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV63795840, COSV63799317; called by muse, mutect2, varscan2
- TAS2R3 | c.197G>C p.S66T | Missense Mutation (SNP) | VAF 70/182 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.023); catalogued as COSV56092985; called by muse, mutect2, varscan2
- TIMM8A | c.225G>C p.Q75H | Missense Mutation (SNP) | VAF 40/284 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0.025); catalogued as COSV58124268; called by muse, mutect2, varscan2
- TUBB4A | c.761C>A p.A254D | Missense Mutation (SNP) | VAF 57/128 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.544); catalogued as COSV51158381, COSV51165854, COSV51169526; called by muse, mutect2, varscan2
- TULP1 | c.355G>A p.E119K | Missense Mutation (SNP) | VAF 41/100 reads (41%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.001); catalogued as COSV57694130; called by muse, mutect2, varscan2
- UBQLN1 | c.1466G>A p.G489E | Missense Mutation (SNP) | VAF 48/122 reads (39%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.549); catalogued as COSV57409755; called by muse, mutect2
- UBQLN2 | c.1163C>T p.S388L | Missense Mutation (SNP) | VAF 51/98 reads (52%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.906); catalogued as rs758685386, COSV57740886; called by muse, mutect2, varscan2
- XDH | c.343T>C p.F115L | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV65151490; called by muse, mutect2, varscan2
- ZCCHC7 | c.296G>C p.S99T | Missense Mutation (SNP) | VAF 77/177 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59721427; called by muse, mutect2, varscan2
- CLSTN3 | c.400_414del p.R134_V138del | In Frame Del (DEL) | VAF 46/134 reads (34%) | called by pindel, varscan2
- CLSTN3 | c.416A>C p.N139T | Missense Mutation (SNP) | VAF 60/157 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- LATS2 | c.238del p.I80Sfs*20 | Frame Shift Del (DEL) | VAF 84/241 reads (35%) | called by mutect2, pindel, varscan2
- SOX9 | c.788dup p.R264Qfs*32 | Frame Shift Ins (INS) | VAF 22/54 reads (41%) | called by mutect2, varscan2
- AKT1 | c.852G>A p.K284= | Silent (SNP) | VAF 118/284 reads (42%) | catalogued as COSV62576603; called by muse, mutect2, varscan2
- BCL11A | c.1134C>T p.H378= (on ENST00000335712 / NM_001365609.1; = p.H412= on NM_018014.4) | Silent (SNP) | VAF 58/113 reads (51%) | catalogued as rs1392606372, COSV59638590; called by muse, mutect2, varscan2
- COG7 | c.2187G>A p.P729= | Silent (SNP) | VAF 73/156 reads (47%) | catalogued as rs759094324, COSV56151706; ClinVar: likely benign; called by muse, mutect2, varscan2
- FBXL4 | c.1722G>T p.P574= | Silent (SNP) | VAF 20/59 reads (34%) | catalogued as COSV57750481; called by muse, mutect2, varscan2
- HEATR6 | c.1917G>A p.T639= | Silent (SNP) | VAF 44/85 reads (52%) | catalogued as rs752529908, COSV51749563; called by muse, mutect2, varscan2
- ILVBL | c.1749G>A p.G583= | Silent (SNP) | VAF 39/105 reads (37%) | catalogued as COSV54623352; called by muse, mutect2, varscan2
- KCNA6 | c.522G>A p.R174= | Silent (SNP) | VAF 56/114 reads (49%) | catalogued as COSV54978432; called by muse, mutect2
- OR8B8 | c.42C>T p.L14= | Silent (SNP) | VAF 41/92 reads (45%) | catalogued as rs137869845; called by muse, mutect2, varscan2
- PCDHGA4 | c.636C>T p.D212= | Silent (SNP) | VAF 58/140 reads (41%) | catalogued as rs750434737, COSV53977600; called by muse, mutect2, varscan2
- POF1B | c.705A>G p.S235= | Silent (SNP) | VAF 63/150 reads (42%) | catalogued as COSV53141602; called by muse, mutect2, varscan2
- POLA1 | c.2829C>T p.D943= | Silent (SNP) | VAF 152/311 reads (49%) | catalogued as COSV66891429; called by muse, mutect2, varscan2
- PRAMEF12 | c.276G>A p.K92= | Silent (SNP) | VAF 37/96 reads (39%) | catalogued as COSV100743723, COSV63216858; called by muse, mutect2, varscan2
- PRKAR1B | c.381G>A p.A127= | Silent (SNP) | VAF 115/249 reads (46%) | catalogued as rs748586275, COSV64320287; called by muse, mutect2, varscan2
- RBM25 | c.369C>T p.S123= | Silent (SNP) | VAF 176/431 reads (41%) | catalogued as rs903377880, COSV56203409, COSV99998802; called by muse, mutect2, varscan2
- SIRT7 | c.729G>A p.G243= | Silent (SNP) | VAF 43/106 reads (41%) | catalogued as COSV58712861; called by muse, mutect2, varscan2
- SNX27 | c.1557C>T p.C519= | Silent (SNP) | VAF 84/630 reads (13%) | catalogued as rs900163200, COSV64326304; called by muse, mutect2, varscan2
- SPTB | c.3996C>A p.I1332= | Silent (SNP) | VAF 159/343 reads (46%) | catalogued as COSV67630335, COSV67635680; called by muse, mutect2, varscan2
- TLN2 | c.5778C>T p.H1926= | Silent (SNP) | VAF 21/41 reads (51%) | catalogued as rs769000863, COSV60896961; called by muse, mutect2, varscan2
- USP40 | c.1797G>A p.Q599= | Silent (SNP) | VAF 8/194 reads (4%) | catalogued as COSV52489500; called by muse, mutect2
- DLG3 | c.1820-1328C>G | Intron (SNP) | VAF 123/300 reads (41%) | catalogued as COSV52086230, COSV52088074; called by muse, mutect2, varscan2
